CTSP case CTSP-B02D — CTSP-DLBCL1: CTSP Diffuse Large B-Cell Lymphoma (DLBCL) CALGB 50303
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2f49bfda-f7e2-4d2e-8cc5-95aa7173ba88

Demographics
Sex at birth: female; Race: asian; Year of birth: 1954; Vital status: Dead; Days to death: 286 days; Year of death: 2011; Cause of death: Cancer Related.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Age at diagnosis: 56.8 years (20,759 days); Method of diagnosis: Biopsy; Ann Arbor pathologic stage: Stage IV; Days to last follow up: 286 days; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High Risk.

Biospecimens (1 sample)
- Sample DLBCL11317-sample: Sample type: Tumor; Tissue type: Tumor.
